Gene-level copy-number profile of tumor specimen C3L-02964-01 from CPTAC case C3L-02964, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 58.0 years (21,194 days).
Specimen C3L-02964-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 907ddd40-3c81-4045-89c6-56137ae00715.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-02964-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,705 have no estimate.
https://portal.gdc.cancer.gov/files/a1de8149-411e-4378-b593-bef9f587e680

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,855; copy number 2: 54,418; copy number 3: 1,565; copy number 4: 22; copy number 6: 58.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 58 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:37,326,575–38,973,912, 58 genes, copy number 6 (within-gene range 2–6): AC091182.1, AC091182.2, LINC01605, AC124067.1, AC124067.2, AC124067.3, AC124067.4, AC137579.2, AC137579.1, RNU6-607P, ZNF703, AC138356.3, AC138356.1, ERLIN2, AC138356.2, PLPBP, ADGRA2, BRF2, RAB11FIP1, AC130304.1, RN7SL709P, GOT1L1, AC144573.1, ADRB3, RPL12P48, EIF4EBP1, AP006545.1, AP006545.2, ASH2L, RNU6-988P, AC084024.1, STAR, AC084024.3, LSM1, RNU6-323P, BAG4, AC084024.2, AC084024.4, DDHD2, PLPP5, NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1, RNF5P1, AC016813.1, TACC1, Y_RNA, AC067817.1, AC067817.2, PLEKHA2.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
